Somatic mutation profile of tumor specimen MP2PRT-PAVUTC-TMP1-A (aliquot MP2PRT-PAVUTC-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVUTC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,071 days).
Specimen MP2PRT-PAVUTC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60936393-89df-460c-8e12-c57bfed312bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVUTC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVUTC-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff701d37-62dd-45a0-9b3f-61a501f458b9

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, 3'Flank 1, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EZHIP | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 148/498 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1557318879, COSV100539415; called by muse, mutect2, varscan2
- NTN4 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs1420249786; called by muse, mutect2, varscan2
- PTCHD1 | c.543G>C p.K181N | Missense Mutation (SNP) | VAF 130/431 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV65061201; called by muse, mutect2, varscan2
- SH3D19 | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 32/376 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as rs376194040; called by muse, mutect2
- TPRG1 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 85/257 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs370291238; called by muse, mutect2, varscan2
- DENND11 | c.244_245insGGGCCG p.F81_V82insGA | In Frame Ins (INS) | VAF 88/368 reads (24%) | called by mutect2, pindel, varscan2
- IGHV1-69 | c.350_351insGGGAGGG p.*118Gfs*? | Frame Shift Ins (INS) | VAF 22/79 reads (28%) | called by pindel, varscan2
- IL16 | c.71T>C p.M24T | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- MGAM | c.4027T>C p.Y1343H | Missense Mutation (SNP) | VAF 73/287 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MXI1 | c.5A>G p.E2G | Missense Mutation (SNP) | VAF 88/320 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDH7 | c.2738A>C p.E913A | Missense Mutation (SNP) | VAF 19/416 reads (5%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.9); called by muse, mutect2
- ADAMTS15 | c.2835C>T p.C945= | Silent (SNP) | VAF 84/286 reads (29%) | catalogued as rs745751631; called by muse, mutect2, varscan2
- MMP15 | c.1344C>T p.P448= | Silent (SNP) | VAF 28/468 reads (6%) | catalogued as rs151142416; called by muse, mutect2
- PTPN14 | c.2799C>T p.N933= | Silent (SNP) | VAF 75/302 reads (25%) | catalogued as rs770612272, COSV65286133; called by muse, mutect2, varscan2
- IGKV1D-16 | chr2:90100739 del CCCA | 3'Flank (DEL) | VAF 54/134 reads (40%) | called by mutect2, pindel, varscan2
